Gene-level copy-number profile of tumor specimen TCGA-CM-4748-01A from TCGA case TCGA-CM-4748, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 53.4 years (19,509 days).
Specimen TCGA-CM-4748-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.cc543584-e3b3-49d3-97f6-120c13d83798.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CM-4748-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/030df395-7f2d-4e65-ab6c-199bdc7cec53

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 2,805; copy number 2: 57,011.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CM-4748-01A-01D-1406-01): tumor purity 0.63, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:3,466,250–3,478,978, 1 gene: GAPLINC.
- chr18:3,571,215–3,598,363, 3 genes: RN7SL39P, AP002472.1, DLGAP1-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 419. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
